Somatic mutation profile of tumor specimen TCGA-FS-A1ZH-06A (aliquot TCGA-FS-A1ZH-06A-11D-A197-08) from TCGA case TCGA-FS-A1ZH, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 72.0 years (26,289 days).
Specimen TCGA-FS-A1ZH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4a959f55-02eb-4330-9c00-559b12550a26.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FS-A1ZH-10A (Blood Derived Normal), aliquot TCGA-FS-A1ZH-10A-01D-A199-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/125660e5-7c65-45b2-a8ca-2df7abba9bcd

The open-access MAF lists 35 somatic variants for this specimen: 24 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 10, Splice Site 2, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- PPP6C | c.809C>T p.S270L | Missense Mutation (SNP) | VAF 36/57 reads (63%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.631); catalogued as rs1481246558, COSV65207385; called by muse, mutect2, varscan2
- BOP1 | c.341C>T p.A114V | Missense Mutation (SNP) | VAF 21/95 reads (22%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs1297908597; called by muse, varscan2
- C1QC | c.301C>T p.P101S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.75); PolyPhen benign (0.076); catalogued as COSV65889368; called by muse, mutect2, varscan2
- CD300E | c.330G>C p.W110C | Missense Mutation (SNP) | VAF 27/145 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs753438342, COSV60790093; called by muse, mutect2, varscan2
- CHI3L2 | c.188T>G p.F63C | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63873634; called by muse, mutect2, varscan2
- DDX20 | c.1313-1G>A p.X438_splice | Splice Site (SNP) | VAF 62/180 reads (34%) | catalogued as COSV63778286; called by muse, mutect2, varscan2
- DDX60 | c.3541G>A p.E1181K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.5); PolyPhen benign (0.015); catalogued as rs1255485179, COSV67095741; called by muse, mutect2, varscan2
- DNAH8 | c.5533G>A p.A1845T | Missense Mutation (SNP) | VAF 39/120 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as rs756311363, COSV59433688; called by muse, mutect2, varscan2
- DPP6 | c.280A>G p.K94E (on ENST00000377770 / NM_001364500.2; = p.K32E on NM_001936.5) | Missense Mutation (SNP) | VAF 33/125 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs778160963, COSV59603756; called by muse, mutect2, varscan2
- EDN3 | c.412G>A p.G138S | Missense Mutation (SNP) | VAF 35/119 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.135); catalogued as COSV61107205; called by muse, mutect2, varscan2
- ELK3 | c.1031G>A p.S344N | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57385985; called by muse, mutect2, varscan2
- FAM217A | c.601G>A p.D201N | Missense Mutation (SNP) | VAF 35/138 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51159298; called by muse, mutect2, varscan2
- FLT3 | c.2137A>G p.T713A | Missense Mutation (SNP) | VAF 21/136 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.18); catalogued as COSV54048315; called by muse, mutect2, varscan2
- HSPBP1 | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 15/36 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs373339365; called by muse, mutect2, varscan2
- MOB2 | c.451G>A p.V151M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1402632314, COSV57318120; called by muse, mutect2, varscan2
- MYO15A | c.968C>T p.S323L | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1314383043, COSV52754013; called by muse, mutect2, varscan2
- RBM33 | c.1418G>A p.S473N | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.02); catalogued as COSV56630366; called by muse, mutect2, varscan2
- SORCS1 | c.2476G>T p.G826C | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53851054; called by muse, varscan2
- SPPL2A | c.1487A>T p.Q496L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.231); catalogued as COSV55940376; called by muse, mutect2, varscan2
- TMEM74 | c.781C>T p.R261C | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1312758444, COSV52462842; called by muse, mutect2, varscan2
- TNS1 | c.385C>T p.H129Y | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV50694313; called by muse, mutect2, varscan2
- ZNF609 | c.725T>C p.L242P | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.015); catalogued as COSV58581487; called by muse, mutect2, varscan2
- THNSL2 | c.571+6_571+7del p.X191_splice | Splice Site (DEL) | VAF 13/55 reads (24%) | called by pindel, varscan2
- CDH11 | c.1842C>A p.G614= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV51751613; called by muse, mutect2, varscan2
- FGR | c.1554C>T p.S518= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as rs769952592, COSV64969362; called by muse, mutect2, varscan2
- HMCN1 | c.231T>A p.P77= | Silent (SNP) | VAF 38/126 reads (30%) | catalogued as rs376088038, COSV54886777; called by muse, mutect2, varscan2
- RAB11FIP1 | c.2691C>T p.V897= | Silent (SNP) | VAF 22/83 reads (27%) | catalogued as COSV54757850; called by muse, mutect2, varscan2
- SAMSN1 | c.348G>A p.E116= | Silent (SNP) | VAF 64/212 reads (30%) | catalogued as COSV53469031; called by muse, mutect2, varscan2
- SORBS2 | c.1236G>A p.E412= | Silent (SNP) | VAF 18/87 reads (21%) | catalogued as COSV52994776; called by muse, mutect2, varscan2
- TC2N | c.1170C>T p.F390= | Silent (SNP) | VAF 50/178 reads (28%) | catalogued as rs776984565, COSV61746360, COSV61747345; called by muse, mutect2, varscan2
- TLK2 | c.238A>C p.R80= | Silent (SNP) | VAF 4/24 reads (17%) | catalogued as COSV58298297; called by muse, mutect2, varscan2
- UNC45A | c.2517C>T p.A839= | Silent (SNP) | VAF 38/416 reads (9%) | catalogued as rs1008350719, COSV67793550; called by muse, mutect2
- WHRN | c.480G>A p.S160= | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as COSV99470566; called by muse, mutect2, varscan2
- MIR1-1HG-AS1 | n.736C>T | RNA (SNP) | VAF 18/77 reads (23%) | called by muse, mutect2, varscan2
